Gene-level copy-number profile of tumor specimen C3N-02181-02 from CPTAC case C3N-02181, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.1 years (19,396 days).
Specimen C3N-02181-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 398299b3-de82-49f8-83f0-a2f8c2dbe053.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02181-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/55b66086-be8b-4360-8b46-d043f1ff106a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 5,607; copy number 2: 47,111; copy number 3: 5,593; copy number 35: 15.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,326,131–50,423,443, 4 genes: AL596275.1, HMGB1P45, FCF1P6, DMRTA2.
- chr1:50,780,340–50,974,634, 3 genes (within-gene range 0–1): PHBP12, MRPS6P2, CDKN2C.
- chr9:21,638,285–26,644,595, 40 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1.
- chr10:99,875,577–100,009,947, 2 genes: DNMBP, DNMBP-AS1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,905,354–42,452,051, 15 genes, copy number 35: MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1.

Autosomal genes at a single copy (total copy number 1): 5,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
